Somatic mutation profile of tumor specimen TCGA-17-Z056-01A (aliquot TCGA-17-Z056-01A-01W-0747-08) from TCGA case TCGA-17-Z056, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9f0ac9-9a24-4ab2-ad53-b6243e8e9d8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z056-11A (Solid Tissue Normal), aliquot TCGA-17-Z056-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63217e43-6ec7-43d9-9d3b-b1c23869f628

The open-access MAF lists 485 somatic variants for this specimen: 381 protein-altering or splice-affecting, 90 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 90, Nonsense Mutation 28, Splice Site 12, Intron 7, Frame Shift Del 5, Splice Region 3, 3'UTR 3, RNA 3, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic; called by muse, mutect2
- ABCB1 | c.3796A>C p.I1266L | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55965670; called by muse, mutect2
- ACTC1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.946); catalogued as COSV51757689; called by muse, mutect2
- ADAMTS20 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs1005720002, COSV67135895; called by muse, mutect2
- ADCY8 | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 96/1037 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53903165; called by muse, mutect2
- ADGRB3 | c.552del p.R185Efs*28 | Frame Shift Del (DEL) | VAF 40/239 reads (17%) | catalogued as COSV65408438; called by mutect2, pindel, varscan2
- AHNAK | c.17237C>T p.S5746L | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99948795; called by muse, mutect2
- ANO3 | c.2399G>T p.R800M | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99880025; called by muse, mutect2, varscan2
- APC | c.8194G>T p.D2732Y | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99967717; called by muse, mutect2
- APOB | c.10263G>T p.M3421I | Missense Mutation (SNP) | VAF 16/429 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV51933873; called by muse, mutect2
- ARPC1B | c.707+1G>A p.X236_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | catalogued as COSV53163433; called by muse, mutect2
- ASIC2 | c.844C>A p.L282M | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56770574; called by muse, mutect2, varscan2
- B3GALT1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV59908514; called by muse, mutect2
- BLK | c.1057C>A p.R353S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs199696853, COSV99376946; called by muse, mutect2, varscan2
- BRINP3 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV99054906; called by muse, mutect2
- BTBD11 | c.1178C>A p.P393Q | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104383490; called by muse, mutect2, varscan2
- CACNA1C | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 22/228 reads (10%) | catalogued as rs1555878994, COSV59712986; called by muse, mutect2, varscan2
- CACNA1G | c.5969T>C p.I1990T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.033); catalogued as rs1352004427; called by muse, mutect2
- CADPS2 | c.582G>C p.L194F | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1188136337, COSV100465551; called by muse, mutect2
- CCER1 | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs561247270, COSV100727030; called by muse, mutect2, varscan2
- CCL17 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs567664586; called by muse, mutect2, varscan2
- CD244 | c.879del p.S294Afs*6 (on ENST00000368033 / NM_001166663.2; = p.S289Afs*6 on NM_016382.4) | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as COSV100458837; called by pindel, varscan2
- CDK18 | c.1103G>A p.R368K (on ENST00000506784 / NM_212503.3; = p.R338K on NM_002596.4) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1389161412; called by muse, mutect2
- CELF5 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs779765913, COSV53010905; called by muse, mutect2, varscan2
- CHN1 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as COSV55033142; called by muse, mutect2, varscan2
- CLEC4D | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs756477421, COSV55230477; called by muse, mutect2, varscan2
- CMA1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV51625229; called by muse, mutect2
- CMYA5 | c.2149C>G p.R717G | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs200554337; called by muse, mutect2, varscan2
- CNMD | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as rs1156509353, COSV100139753; called by muse, mutect2
- COL11A1 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as rs1448065580, COSV100617044, COSV62178528; called by muse, mutect2
- COL22A1 | c.2142C>T p.G714= | Splice Region (SNP) | VAF 31/154 reads (20%) | catalogued as rs747935376; called by muse, mutect2, varscan2
- COL9A2 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65607876; called by muse, mutect2
- CPA1 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM139176; called by muse, mutect2
- CPS1 | c.2944G>T p.G982C | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM063937; called by muse, mutect2, varscan2
- CPXM2 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53867301; called by muse, mutect2
- CSMD1 | c.1621G>T p.G541C (on ENST00000520002; = p.G540C on NM_033225.6) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59313264; called by muse, mutect2, varscan2
- CSMD3 | c.3767A>T p.N1256I (on ENST00000297405 / NM_001363185.1; = p.N1152I on NM_052900.3) | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52261998; called by muse, mutect2
- CTNND2 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1257313064; called by mutect2, varscan2
- DNASE1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as rs140382618; called by muse, mutect2, varscan2
- DPYSL5 | c.1466G>C p.R489P | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV56514713; called by muse, mutect2, varscan2
- EMC7 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV56627035; called by muse, mutect2, varscan2
- FAM13C | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 53/762 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV53242682, COSV53256734; called by muse, mutect2
- FANCM | c.3692C>T p.T1231I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV57503966; called by muse, mutect2, varscan2
- FLG2 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 39/624 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781008368, COSV66171720; called by muse, mutect2
- FOXN2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs772517400; called by muse, mutect2
- GABRA6 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99194195; called by muse, mutect2
- GABRB2 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.326); catalogued as COSV50965975; called by muse, mutect2, varscan2
- GALNTL6 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV71827776; called by muse, mutect2
- GGCT | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 15/256 reads (6%) | catalogued as rs758508499, COSV50040810, COSV50041071; called by muse, mutect2
- GIMAP8 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV56234416; called by muse, mutect2, varscan2
- GLI3 | c.2292A>T p.Q764H | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as CD972244; called by muse, mutect2
- GSTA2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101534025, COSV72415610; called by muse, mutect2, varscan2
- HTR1A | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 32/762 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60503174; called by muse, mutect2
- IFT140 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV68486029; called by muse, mutect2, varscan2
- IGSF5 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV66030191; called by muse, mutect2, varscan2
- KCNK13 | c.889G>T p.G297W | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.6); catalogued as rs768523004, COSV56411077; called by muse, mutect2, varscan2
- KDR | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55774920; called by muse, varscan2
- KIAA0319L | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1197541921; called by muse, mutect2, varscan2
- KMT2A | c.9538C>A p.P3180T | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs781903029; called by muse, mutect2, varscan2
- KRTAP10-4 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59951992; called by muse, mutect2
- LAIR2 | c.179T>A p.L60Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56622540; called by muse, mutect2, varscan2
- LBP | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54139544; called by muse, mutect2
- LRFN5 | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53277199; called by muse, mutect2
- LRIT2 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs947932172, COSV60562125; called by muse, mutect2
- LRRC10 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100825480; called by muse, mutect2
- LRRC66 | c.818G>A p.W273* | Nonsense Mutation (SNP) | VAF 38/505 reads (8%) | catalogued as rs1229596276, COSV58635716; called by muse, mutect2
- LRRIQ3 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 26/314 reads (8%) | catalogued as COSV63041605; called by muse, mutect2
- LRRIQ3 | c.1200G>T p.L400F | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs1368480756, COSV100598527, COSV100599519; called by muse, mutect2
- LRRK2 | c.6463A>T p.M2155L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs201614703; called by muse, mutect2, varscan2
- MC5R | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201046123; called by muse, mutect2, varscan2
- MFAP3L | c.549G>C p.E183D | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64372464; called by muse, mutect2, varscan2
- MTMR12 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774307795; called by muse, mutect2, varscan2
- MYOC | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM973393; called by muse, mutect2
- NAV3 | c.1736G>T p.C579F | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV57104978; called by muse, mutect2, varscan2
- NGB | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV53611443; called by muse, mutect2, varscan2
- NLE1 | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs187705654; called by muse, mutect2
- NLRP5 | c.2711A>T p.N904I | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368457078; called by muse, mutect2, varscan2
- NPAP1 | c.1538G>C p.R513T | Missense Mutation (SNP) | VAF 97/559 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100275073; called by muse, mutect2, varscan2
- NRDE2 | c.322A>C p.S108R | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs367803290; called by muse, mutect2, varscan2
- NRK | c.1162del p.E388Nfs*42 | Frame Shift Del (DEL) | VAF 12/100 reads (12%) | catalogued as rs1328508612, COSV99688736; called by mutect2, pindel, varscan2
- NSD1 | c.6970G>A p.G2324R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs761745615; called by muse, mutect2, varscan2
- OR2J2 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 154/670 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs758575002, COSV101013318; called by muse, varscan2
- OR2T8 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 56/377 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60663588; called by muse, mutect2, varscan2
- OR3A2 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs267604817; called by mutect2, varscan2
- OR4F5 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 31/274 reads (11%) | catalogued as rs776332430; called by muse, mutect2, varscan2
- OR52B4 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139777859; called by muse, mutect2
- OR5D14 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59455806; called by muse, mutect2, varscan2
- PCDHGA1 | c.1990G>T p.V664L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); catalogued as COSV65296000; called by muse, mutect2, varscan2
- PLPPR4 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV64570386; called by muse, mutect2
- PLXNA4 | c.1313A>T p.Y438F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs202115162; called by muse, mutect2, varscan2
- PRAME | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1185943971; called by muse, mutect2, varscan2
- PTBP2 | c.272G>T p.G91V (on ENST00000426398 / NM_001300986.2; = p.G83V on NM_021190.4) | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64624067; called by muse, mutect2
- PUS1 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777605316, COSV59035399; called by muse, mutect2, varscan2
- RIMS2 | c.1138G>T p.D380Y (on ENST00000666250 / NM_001348490.2; = p.D188Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51681919, COSV51731720; called by muse, mutect2, varscan2
- RYR2 | c.12961G>A p.G4321S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV63657690, COSV63663924; called by muse, mutect2, varscan2
- SCN2A | c.1103A>T p.D368V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559355584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEM1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1163080479; called by muse, mutect2, varscan2
- SKA3 | c.370T>A p.S124T | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV53436652; called by muse, mutect2, varscan2
- SLC25A52 | c.550C>T p.R184* (on ENST00000672005; = p.R174* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 31/207 reads (15%) | catalogued as rs568244554; called by muse, mutect2, varscan2
- SLC39A12 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs779506707; called by muse, mutect2, varscan2
- SLC9A6 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV104425116; called by muse, varscan2
- SNTG1 | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52458390; called by muse, mutect2, varscan2
- SORCS1 | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53871533; called by muse, mutect2
- SPATA33 | c.209-1G>C p.X70_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as COSV56377734; called by muse, varscan2
- STIL | c.3832A>T p.K1278* | Nonsense Mutation (SNP) | VAF 20/234 reads (9%) | catalogued as COSV54552293; called by muse, mutect2
- SV2C | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); catalogued as COSV100456970; called by muse, mutect2, varscan2
- SYNJ1 | c.4582G>A p.D1528N | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); catalogued as rs755488018; called by muse, varscan2
- SYNPO2 | c.3262C>A p.R1088S | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV61118687; called by muse, varscan2
- TMCO6 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99347014; called by muse, mutect2
- TMEM132D | c.2570C>A p.T857K | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67162794, COSV99066529; called by muse, mutect2
- TRIM48 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV70161958, COSV70162436, COSV70163489; called by muse, mutect2
- TTC16 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100077033; called by muse, mutect2, varscan2
- UACA | c.3819T>A p.D1273E | Missense Mutation (SNP) | VAF 72/552 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs760836364; called by muse, mutect2, varscan2
- UGT1A7 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 74/537 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs368267055; called by muse, mutect2, varscan2
- USP24 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1194370436; called by muse, mutect2, varscan2
- VNN1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63390530; called by muse, mutect2, varscan2
- WNK3 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100671338; called by muse, mutect2
- XDH | c.3244G>A p.V1082I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV65148445; called by muse, mutect2, varscan2
- ZCWPW1 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs767927507; called by muse, mutect2, varscan2
- ZFHX4 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 9/134 reads (7%) | catalogued as COSV51492712; called by muse, mutect2
- ZMYM6 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV58185130; called by muse, mutect2
- ZNF165 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs757188413, COSV66103032; called by muse, mutect2, varscan2
- ZNF430 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV55108124; called by muse, mutect2, varscan2
- ABCB4 | c.1879C>A p.L627I | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ABCC11 | c.2642C>A p.S881* | Nonsense Mutation (SNP) | VAF 45/173 reads (26%) | called by muse, mutect2, varscan2
- AC008397.2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AC013489.1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ACAN | c.5177G>T p.S1726I | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- ACKR1 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSL1 | c.1730A>G p.Y577C | Missense Mutation (SNP) | VAF 132/810 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ADAMTS20 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- ADAMTS3 | c.1052A>C p.D351A | Missense Mutation (SNP) | VAF 8/231 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY2 | c.3088A>G p.R1030G | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADPRS | c.1001A>T p.Q334L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.08); called by muse, mutect2
- AKR1E2 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2
- ALG3 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALOX15B | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALX1 | c.704T>A p.V235E | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.573); called by muse, mutect2
- AMPD1 | c.1191T>C p.A397= | Splice Region (SNP) | VAF 23/248 reads (9%) | called by muse, mutect2
- AMPH | c.1367C>G p.T456S | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- APOL3 | c.740C>G p.S247* (on ENST00000349314 / NM_145640.2; = p.S176* on NM_014349.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- AQR | c.1850A>T p.N617I | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ARHGAP12 | c.2311C>G p.Q771E | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2
- ARID5B | c.3191G>C p.G1064A | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- ATP11C | c.737A>T p.N246I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ATP2A2 | c.1422C>T p.V474= | Splice Region (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- ATP7B | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.791); called by muse, varscan2
- BHMT | c.638T>A p.I213N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- BNIP5 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- BTC | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 38/586 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2
- CA6 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); called by muse, mutect2
- CALCR | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.136); called by muse, mutect2
- CAPN11 | c.1775A>G p.Q592R | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- CCDC103 | c.383del p.G128Vfs*51 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- CCDC39 | c.651T>A p.H217Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- CCDC60 | c.1234C>A p.Q412K | Missense Mutation (SNP) | VAF 159/889 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CCER1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCT4 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CD1E | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- CENPF | c.1221C>G p.F407L | Missense Mutation (SNP) | VAF 136/716 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP126 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CEP250 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CFAP47 | c.641T>A p.V214E | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CLCA2 | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2
- CNTNAP5 | c.1316T>C p.I439T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.342); called by muse, mutect2
- COL15A1 | c.3971G>T p.W1324L | Missense Mutation (SNP) | VAF 64/650 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- COL19A1 | c.467A>T p.Y156F | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COLGALT2 | c.1059G>C p.K353N | Missense Mutation (SNP) | VAF 20/649 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.281); called by muse, mutect2
- COMMD3-BMI1 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by mutect2, varscan2
- CPM | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CRB1 | c.1190A>T p.D397V | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRNKL1 | c.2350A>C p.K784Q | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- CUL1 | c.1389G>C p.Q463H | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL4A | c.1719G>T p.L573F (on ENST00000375440 / NM_001008895.4; = p.L473F on NM_003589.3) | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- DACH1 | c.1807C>T p.P603S (on ENST00000619232 / NM_001366712.1; = p.P349S on NM_004392.6) | Missense Mutation (SNP) | VAF 136/844 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DCDC1 | c.4004T>A p.L1335Q (on ENST00000597505 / NM_001367979.1; = p.L442Q on NM_020869.3) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- DCDC1 | c.3427A>C p.N1143H (on ENST00000597505 / NM_001367979.1; = p.N250H on NM_020869.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- DDIT4 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2
- DDX18 | c.752-1G>C p.X251_splice | Splice Site (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- DDX60L | c.2359G>T p.D787Y | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DENND5B | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DMBT1 | c.5018A>T p.N1673I (on ENST00000338354 / NM_001377530.1; = p.N916I on NM_004406.3) | Missense Mutation (SNP) | VAF 57/541 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.6195G>T p.W2065C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH5 | c.9367G>C p.V3123L | Missense Mutation (SNP) | VAF 50/1008 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- DNAH7 | c.2983A>T p.S995C | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2
- DNAH8 | c.7658G>T p.S2553I | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DUOXA1 | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2LI1 | c.901-2A>T p.X301_splice | Splice Site (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- EPHA7 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EPHA8 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EPHB6 | c.715T>A p.S239T | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2
- FAM117B | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FAM131B | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- FAM199X | c.997-2A>T p.X333_splice | Splice Site (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
- FAM47A | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2
- FAM50B | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAT3 | c.4559C>A p.T1520N | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FCAR | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FFAR3 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2
- FGD6 | c.3896C>G p.S1299C | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2
- FGL2 | c.790T>A p.F264I | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FH | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FLG | c.6377C>G p.S2126C | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FLNB | c.3437G>A p.G1146E | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- FNDC7 | c.1127G>C p.S376T | Missense Mutation (SNP) | VAF 37/487 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- FOSB | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FOXO1 | c.890C>A p.A297E | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2
- GABRA4 | c.1233C>A p.S411R | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- GC | c.365G>C p.C122S | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLRA3 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); called by muse, mutect2
- GLYAT | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGA7B | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2
- GPR151 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GPRASP2 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- GPX6 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GRM5 | c.1838C>G p.S613* | Nonsense Mutation (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- GRM8 | c.1702G>C p.G568R | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GUCA2B | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2
- GUCY1A2 | c.1776G>T p.M592I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GZMA | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAS2 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- HECTD4 | c.2663A>T p.H888L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- HERC2 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HLF | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ICOS | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- IGSF10 | c.3036G>T p.R1012S | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- IL10RB | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- IL16 | c.1839G>C p.K613N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- IMPG2 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, mutect2
- INSYN2A | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITIH1 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMJD1C | c.5830G>A p.G1944R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.701); called by muse, mutect2
- KCNB1 | c.522A>T p.K174N | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KCNH7 | c.2780T>A p.F927Y | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNU1 | c.2332G>T p.G778* | Nonsense Mutation (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2
- KCTD8 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 38/744 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- KIAA0100 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- KIAA1109 | c.9391G>T p.G3131W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIF18A | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIR2DL1 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 93/795 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- KIR3DL3 | c.1160G>C p.C387S | Missense Mutation (SNP) | VAF 71/970 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.465); called by muse, mutect2
- KLHL1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- KLRB1 | c.414+1G>A p.X138_splice | Splice Site (SNP) | VAF 54/243 reads (22%) | called by muse, mutect2, varscan2
- KMT2C | c.12277-1G>C p.X4093_splice | Splice Site (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- LCLAT1 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); called by muse, mutect2
- LCT | c.1502C>A p.P501H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRP1B | c.13336A>G p.I4446V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- LSAMP | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- LTBP2 | c.1911T>A p.C637* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- MACF1 | c.8707G>A p.A2903T | Missense Mutation (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- MACF1 | c.21193G>C p.D7065H (on ENST00000372915; = p.D5110H on NM_012090.5) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- MADD | c.1772A>G p.H591R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEA12 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2
- MAGEB6B | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAGI2 | c.2651G>T p.S884I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MAP3K4 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MBD6 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.489); called by muse, mutect2
- MDGA2 | c.2506G>T p.D836Y (on ENST00000399232 / NM_001113498.2; = p.D538Y on NM_182830.4) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MRGPRX4 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTG2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MTMR14 | c.1844C>A p.T615K (on ENST00000296003 / NM_001077525.3; = p.T503K on NM_022485.5) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC16 | c.38845C>T p.Q12949* | Nonsense Mutation (SNP) | VAF 176/1090 reads (16%) | called by muse, mutect2, varscan2
- MUC6 | c.3814C>A p.P1272T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.061); called by muse, varscan2
- MYOCD | c.2710T>A p.F904I | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2
- NAA25 | c.768A>C p.L256F | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- NALCN | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.287); called by muse, mutect2
- NCKAP5 | c.4583C>G p.S1528C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NDUFAF7 | c.362T>A p.V121E | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIPBL | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NIT1 | c.464T>A p.V155E | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- NLRP2 | c.2933T>A p.L978H | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP5 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NME8 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.543); called by muse, mutect2
- NRXN1 | c.1984G>T p.V662F | Missense Mutation (SNP) | VAF 220/882 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.369); called by mutect2, varscan2
- NTSR1 | c.1032C>A p.Y344* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- OLFM3 | c.1339A>T p.N447Y (on ENST00000338858 / NM_001288821.1; = p.N427Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/668 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OLFM4 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OOSP2 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by mutect2, varscan2
- OR11H4 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- OR2B6 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- OR4C6 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 69/574 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR5AP2 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR5L2 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR6Y1 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2
- OR8G2P | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR8H2 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 49/683 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2
- OTOF | c.5266A>C p.K1756Q (on ENST00000272371 / NM_194248.3; = p.K989Q on NM_004802.4) | Missense Mutation (SNP) | VAF 26/337 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); called by muse, mutect2
- OVOL2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAQR8 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PATE1 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 85/548 reads (16%) | called by muse, mutect2, varscan2
- PATJ | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 28/475 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- PATJ | c.4194A>T p.L1398F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2
- PBX2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCARE | c.2084A>T p.E695V | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2
- PCDH17 | c.3263C>G p.P1088R | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCDHB14 | c.2209G>T p.V737L | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); called by muse, mutect2
- PEX5L | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHYHIP | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PIK3C2B | c.2985G>T p.W995C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIKFYVE | c.3448A>T p.R1150* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- PKD1L1 | c.6344G>A p.S2115N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2
- PLOD2 | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLA1 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 30/1066 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- POU2F1 | c.1970G>A p.G657E (on ENST00000541643 / NM_001365848.1; = p.G680E on NM_002697.4) | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- PPIP5K2 | c.3242A>C p.Y1081S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRDM1 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PRICKLE1 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- PRPF8 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSG3 | c.1148A>T p.Q383L | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- PSG7 | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 240/1255 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRB | c.640A>T p.M214L | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRZ1 | c.2908C>A p.P970T | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RAD23A | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAD50 | c.2265G>C p.Q755H | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- RASAL2 | c.1376A>T p.Q459L | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.76); called by muse, mutect2
- RGS21 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS9 | c.1212T>A p.Y404* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- RSAD2 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- SCN10A | c.5812_5815del p.S1938Qfs*13 | Frame Shift Del (DEL) | VAF 56/309 reads (18%) | called by mutect2, pindel, varscan2
- SCN7A | c.5008G>C p.D1670H | Missense Mutation (SNP) | VAF 64/555 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SCRN3 | c.1223A>T p.K408I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SEMA3A | c.1681G>T p.G561* | Nonsense Mutation (SNP) | VAF 50/221 reads (23%) | called by muse, mutect2, varscan2
- SHBG | c.853-1G>A p.X285_splice | Splice Site (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- SIM2 | c.511A>G p.R171G | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- SKAP1 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 58/540 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A19 | c.644-1G>C p.X215_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- SLC27A6 | c.1633G>T p.V545F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- SLCO6A1 | c.1274C>A p.A425E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, varscan2
- SLITRK5 | c.2313C>A p.N771K | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLMAP | c.2118T>A p.C706* (on ENST00000428312 / NM_001377924.1; = p.C768* on NM_007159.5) | Nonsense Mutation (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- SOAT1 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2
- SPARCL1 | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPTA1 | c.3853C>A p.L1285I | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STMN2 | c.289-1G>T p.X97_splice | Splice Site (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- STXBP5L | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SYN3 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SYNJ1 | c.4388C>T p.S1463L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, varscan2
- TBC1D4 | c.2383+1G>C p.X795_splice | Splice Site (SNP) | VAF 5/131 reads (4%) | called by muse, mutect2
- TBX20 | c.801C>A p.Y267* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- TBX3 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TESPA1 | c.703T>A p.F235I (on ENST00000316577 / NM_001098815.3; = p.F97I on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TIAM1 | c.4061C>G p.A1354G | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.072); called by muse, mutect2
- TJP1 | c.752G>T p.R251M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TMCO4 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM169 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TNKS2 | c.1466A>T p.N489I | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TNN | c.2685G>A p.W895* | Nonsense Mutation (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- TRHDE | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- TRIM5 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.342); called by muse, mutect2
- TRPV2 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPV5 | c.227-2A>T p.X76_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- TSPO2 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TTF2 | c.2669G>A p.R890K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2
- TTN | c.71557G>T p.D23853Y (on ENST00000591111; = p.D16429Y on NM_003319.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- UBR2 | c.3846G>T p.Q1282H | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGGT2 | c.4210G>T p.G1404* | Nonsense Mutation (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- UGT2B4 | c.621C>G p.F207L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UNC79 | c.2165G>A p.R722K (on ENST00000393151 / NM_001346218.2; = p.R545K on NM_020818.5) | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- WDR88 | c.297T>A p.S99R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNK4 | c.3665G>C p.S1222T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XCL2 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.49C>T p.P17S (on ENST00000628543; = p.P192S on NM_152381.6) | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.212); called by muse, mutect2
- ZBBX | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 25/794 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ZCCHC17 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFP42 | c.32C>G p.T11R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFYVE1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2
- ZNF10 | c.979_980insT p.G327Vfs*26 | Frame Shift Ins (INS) | VAF 23/152 reads (15%) | called by mutect2, pindel, varscan2
- ZNF154 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2
- ZNF155 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ZNF229 | c.1381T>A p.Y461N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ZNF23 | c.956T>A p.V319D | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF287 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF347 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- ZNF417 | c.1627A>C p.T543P | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF420 | c.841T>A p.C281S | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF513 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ZNF528 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- ZNF594 | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 30/413 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2
- ZNF660 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZNF677 | c.695G>C p.C232S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF765 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ABCB5 | c.2772C>T p.F924= (on ENST00000404938 / NM_001163941.2; = p.F479= on NM_178559.6) | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as COSV99328622; called by muse, mutect2
- ABCF1 | c.84G>A p.V28= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs1168833493; called by mutect2, varscan2
- ABLIM3 | c.540C>A p.T180= | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- ACSM1 | c.366T>C p.P122= | Silent (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- ADGRA3 | c.3612C>T p.N1204= | Silent (SNP) | VAF 26/290 reads (9%) | catalogued as rs146569496; called by muse, mutect2
- ALK | c.2694G>A p.E898= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- ATF6B | c.519C>A p.S173= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs369263490; called by muse, mutect2, varscan2
- BSX | c.330C>A p.R110= | Silent (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- CAPN6 | c.1101G>T p.L367= | Silent (SNP) | VAF 377/2320 reads (16%) | catalogued as COSV60697674; called by muse, mutect2, varscan2
- CDH6 | c.1575T>C p.F525= | Silent (SNP) | VAF 16/340 reads (5%) | called by muse, mutect2
- CDK17 | c.453C>A p.I151= | Silent (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- CHI3L1 | c.879C>G p.T293= | Silent (SNP) | VAF 20/105 reads (19%) | called by muse, varscan2
- CIP2A | c.1851G>T p.V617= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV99842680; called by muse, mutect2
- CNKSR2 | c.1020C>A p.P340= | Silent (SNP) | VAF 148/1071 reads (14%) | called by muse, mutect2, varscan2
- CNTN1 | c.2751T>A p.S917= | Silent (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- COL5A2 | c.2268C>A p.G756= | Silent (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2
- COL6A6 | c.1566A>C p.T522= | Silent (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2, varscan2
- COPG1 | c.1752G>A p.A584= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs889000325, COSV59112752; called by muse, mutect2, varscan2
- CUX2 | c.4432C>A p.R1478= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV55625454; called by mutect2, varscan2
- CYP51A1 | c.141C>T p.V47= | Silent (SNP) | VAF 3/61 reads (5%) | called by muse, mutect2
- DAGLA | c.1065G>A p.R355= | Silent (SNP) | VAF 29/194 reads (15%) | called by muse, mutect2, varscan2
- DISC1 | c.150A>G p.T50= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1235658014, COSV54418625; called by muse, mutect2, varscan2
- DMPK | c.879C>T p.Y293= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- ESX1 | c.1125G>A p.L375= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV65425084; called by muse, varscan2
- FAM47A | c.756C>A p.P252= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100649809; called by muse, mutect2
- FANCA | c.3000C>T p.H1000= | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- FBXO45 | c.732A>G p.E244= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs202142342; called by muse, mutect2, varscan2
- FGR | c.1522C>T p.L508= | Silent (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- FUBP1 | c.678G>T p.P226= | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as COSV53928381; called by muse, mutect2
- GIMAP4 | c.972T>G p.R324= | Silent (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- GLDC | c.2370G>T p.R790= | Silent (SNP) | VAF 93/195 reads (48%) | catalogued as COSV100394727; called by muse, mutect2, varscan2
- GPR52 | c.360C>T p.I120= | Silent (SNP) | VAF 35/488 reads (7%) | catalogued as COSV52296470; called by muse, mutect2
- GRPEL2 | c.588A>T p.A196= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- GSS | c.75G>A p.R25= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs921613586; called by muse, mutect2, varscan2
- IMPG2 | c.144C>T p.L48= | Silent (SNP) | VAF 51/348 reads (15%) | called by muse, mutect2, varscan2
- KCNH1 | c.702G>A p.L234= | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- KCNJ8 | c.312C>T p.Y104= | Silent (SNP) | VAF 363/784 reads (46%) | catalogued as rs765012182, COSV53718078; called by muse, mutect2, varscan2
- KLHL41 | c.1059A>T p.L353= | Silent (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- LRRC30 | c.592C>T p.L198= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs773419266; called by muse, mutect2, varscan2
- LTN1 | c.3390A>T p.L1130= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- MAP7D2 | c.1879C>T p.L627= | Silent (SNP) | VAF 39/550 reads (7%) | called by muse, mutect2
- MTG2 | c.666G>A p.K222= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- NCAPD3 | c.1572G>T p.G524= | Silent (SNP) | VAF 17/227 reads (7%) | called by muse, mutect2
- NEB | c.1506C>T p.F502= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as COSV51444344; called by muse, mutect2, varscan2
- NIT2 | c.240C>A p.L80= | Silent (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- NLRP11 | c.502T>C p.L168= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- NLRP7 | c.216G>A p.V72= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- NOA1 | c.729G>A p.L243= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- NR1I2 | c.723C>T p.P241= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2
- NR2F1 | c.690C>A p.A230= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- OBSCN | c.4284G>C p.R1428= | Silent (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- OR10G8 | c.606T>G p.V202= | Silent (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- OR10Z1 | c.291T>C p.C97= | Silent (SNP) | VAF 50/871 reads (6%) | called by muse, mutect2
- OR13C8 | c.348C>A p.G116= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- OR1E1 | c.189C>A p.L63= | Silent (SNP) | VAF 13/258 reads (5%) | catalogued as COSV59458527; called by muse, mutect2
- OR2T1 | c.318T>A p.L106= | Silent (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- OR8I2 | c.273C>A p.S91= | Silent (SNP) | VAF 30/304 reads (10%) | called by muse, mutect2, varscan2
- PCDH15 | c.4680T>C p.S1560= | Silent (SNP) | VAF 30/310 reads (10%) | called by muse, mutect2
- PDHA2 | c.327G>C p.S109= | Silent (SNP) | VAF 49/272 reads (18%) | called by muse, mutect2, varscan2
- POU4F3 | c.687C>T p.C229= | Silent (SNP) | VAF 22/201 reads (11%) | called by muse, mutect2, varscan2
- PRDM9 | c.2517G>T p.R839= | Silent (SNP) | VAF 53/357 reads (15%) | called by muse, mutect2, varscan2
- PTPDC1 | c.51G>A p.V17= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, varscan2
- RDH16 | c.66G>A p.Q22= | Silent (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- RGS1 | c.576A>G p.K192= | Silent (SNP) | VAF 13/260 reads (5%) | called by muse, mutect2
- RYR3 | c.5004C>A p.S1668= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- SEL1L2 | c.1494T>A p.S498= | Silent (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2
- SETDB1 | c.513C>T p.V171= | Silent (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- SGO1 | c.834A>G p.E278= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2
- SHOX | c.180G>C p.T60= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1219534393; called by muse, mutect2
- SLC13A1 | c.1090C>A p.R364= | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as COSV52015614; called by muse, mutect2, varscan2
- SLC16A12 | c.1230G>A p.A410= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs748432746; called by mutect2, varscan2
- SLC22A10 | c.339A>T p.T113= | Silent (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- SLC35G2 | c.144T>C p.F48= | Silent (SNP) | VAF 20/668 reads (3%) | catalogued as rs1342653404; called by muse, mutect2
- SLC39A10 | c.1504C>T p.L502= | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2, varscan2
- SLC5A6 | c.1146G>A p.L382= | Silent (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
- SLC9A9 | c.1884G>T p.L628= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- SNX19 | c.774C>T p.D258= | Silent (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2
- SORCS3 | c.2430C>T p.T810= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs752984608, COSV63798788; called by muse, mutect2
- SOX3 | c.486C>A p.P162= | Silent (SNP) | VAF 37/224 reads (17%) | catalogued as COSV65168059; called by mutect2, varscan2
- SSTR4 | c.723G>T p.V241= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- SYNE1 | c.21027A>T p.L7009= (on ENST00000367255 / NM_182961.4; = p.L6938= on NM_033071.3) | Silent (SNP) | VAF 28/226 reads (12%) | catalogued as COSV99566687; called by muse, mutect2, varscan2
- TBX3 | c.309C>A p.P103= | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- TCTN3 | c.1539G>T p.P513= | Silent (SNP) | VAF 22/300 reads (7%) | catalogued as COSV56451188; called by muse, mutect2
- TMEM132B | c.1452G>T p.V484= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV54755824; called by muse, mutect2, varscan2
- TMEM171 | c.174G>T p.V58= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- TRPC3 | c.414G>T p.L138= (on ENST00000379645 / NM_001366479.2; = p.L65= on NM_003305.2) | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- WNK1 | c.3348A>T p.S1116= (on ENST00000315939 / NM_018979.4; = p.S869= on NM_014823.3) | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- WWP2 | c.2082C>T p.I694= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- ZC3H7B | c.1629G>T p.L543= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60960971; called by muse, mutect2, varscan2
- ZFP90 | c.1606C>A p.R536= | Silent (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3651G>C | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2627T>A | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- KCNH5 | c.2020-4246G>T | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- MIR505 | n.15G>T | RNA (SNP) | VAF 31/269 reads (12%) | called by muse, mutect2, varscan2
- NLGN4X | c.473-3299C>A | Intron (SNP) | VAF 14/121 reads (12%) | catalogued as rs774170669; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792286 A>T | 3'Flank (SNP) | VAF 7/59 reads (12%) | catalogued as rs1200559093; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18413G>T | Intron (SNP) | VAF 13/107 reads (12%) | catalogued as COSV101045048; called by muse, mutect2, varscan2
- SNORD114-12 | n.63C>A | RNA (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10361-4157G>A | Intron (SNP) | VAF 37/558 reads (7%) | catalogued as rs776175211, COSV59936795; called by muse, mutect2
- TTN | c.10361-4466C>A | Intron (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- UBTFL2 | n.463G>C | RNA (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- VGLL1 | c.688+82G>T | Intron (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- VGLL1 | c.688+83G>T | Intron (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- ZNF197 | c.*2295G>A | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
